Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5184, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5184-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Left renal mass, left partial nephrectomy.

TCGA-BP-5184

Specimens Submitted:

1: KIDNEY, LEFT HILAR, TUMOR, PARTIAL NEPHRECTOMY

DIAGNOSIS:

1. KIDNEY, LEFT HILAR, TUMOR, PARTIAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 3.3 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh for frozen section consultation and is labeled "Left renal hilar tumor, stitch marks deep surgical margin". It consists of a 3.7 x 2.8 x 2.4 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a yellow hemorrhagic mass measuring 3.3 x 2.6 x 2.3cm. The clearance from the resection margin is abutting the inked margin. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

Summary of Sections:

Part 1: KIDNEY, LEFT HILAR, TUMOR, PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	FSC	1
1	M	1
1	RS	1
1	T	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: AREA AT STITCH NEGATIVE FOR TUMOR. RENAL CELL CARCINOMA.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 970e93f0-852a-482e-b74c-dd3ccdcfe8bb (TCGA-BP-5184.2E8C6858-5B76-416C-BC73-EC8359565E0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).